Somatic mutation profile of tumor specimen BA2294D (aliquot aq-BA2294D) from BEATAML1.0 case 2499, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Primary diagnosis: Acute myeloid leukemia with t(8;21)(q22;q22), RUNX1-RUNX1T1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.8 years (22,922 days).
Specimen BA2294D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2fb838bf-4a1b-4885-96be-2f34e3665ecf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2550D (Solid Tissue Normal), aliquot aq-BA2550D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5520c272-152e-40e1-9c1e-292c5b33fdce

The open-access MAF lists 17 somatic variants for this specimen: 14 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Nonsense Mutation 2, Frame Shift Ins 1, 5'UTR 1, Silent 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 9/93 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NAV3 | c.265C>T p.H89Y | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs755938067, COSV57089430; called by muse, mutect2, varscan2
- PCDH7 | c.1264C>T p.R422C | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV62338402; called by muse, varscan2
- TRIM51 | c.995G>C p.G332A | Missense Mutation (SNP) | VAF 40/226 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.907); catalogued as COSV55265158; called by muse, mutect2, varscan2
- ZNF687 | c.2815dup p.R939Pfs*36 | Frame Shift Ins (INS) | VAF 18/99 reads (18%) | catalogued as rs749403447; called by mutect2, varscan2
- ELF1 | c.607G>T p.G203* | Nonsense Mutation (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2
- EPHB1 | c.1418A>G p.E473G | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.266); called by muse, varscan2
- ERI1 | c.266C>A p.S89* | Nonsense Mutation (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- FAM118A | c.510G>C p.K170N | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.019); called by muse, varscan2
- H4C9 | c.118C>A p.R40S | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- HMGCLL1 | c.1015G>A p.V339M | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, varscan2
- PSD4 | c.1783C>G p.L595V | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ZNF236 | c.228T>A p.N76K | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- ZSWIM9 | c.1049C>G p.A350G | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NEDD4L | c.1035C>T p.D345= | Silent (SNP) | VAF 29/93 reads (31%) | catalogued as rs770364514; called by muse, mutect2, varscan2
- BAGE2 | n.149A>T | RNA (SNP) | VAF 22/100 reads (22%) | called by muse, varscan2
- SUGT1 | c.-15C>T | 5'UTR (SNP) | VAF 32/70 reads (46%) | catalogued as rs755551221; called by mutect2, varscan2
